Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A198, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A198-06A (Metastatic).

1015-0-2
Melanoma, NOS

8720/3

12/14/10 lw

PATIENT HISTORY:

Site code: Axilla, subcutaneous tissue C49.3

The patient is a -year-old man with recurrent right chest wall tumor.

PRE-OP DIAGNOSIS: Chest wall tumor, right.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Resection axillary tumor.

FINAL DIAGNOSIS:

SKIN AND SUBCUTIS, AXILLA, RIGHT, RESECTION -

- A. MULTIFOCAL METASTATIC MELANOMA IN SKIN AND SUBCUTANEOUS SOFT TISSUE. THE LARGEST NODULE IS 3.5 CM.
- B. FOCAL INVOLVEMENT OF SOFT TISSUE SURGICAL RESECTION MARGIN BY THE TUMOR.
- C. SKIN WITH DERMAL SCAR AND FOREIGN BODY GIANT CELL REACTION.

Source: NCI Genomic Data Commons file 632465bc-6b80-4ed6-9dc0-727b48f3a1c9 (TCGA-ER-A198.C2698BDC-DB70-48DC-B2CF-AA155C9923F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).